Somatic mutation profile of tumor specimen MMRF_1814_1_BM_CD138pos (aliquot MMRF_1814_1_BM_CD138pos_T1_KBS5U_L07219) from MMRF case MMRF_1814, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.2 years (27,480 days).
Specimen MMRF_1814_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f841051f-a063-4936-b158-9d25aa09fe47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1814_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1814_1_PB_Whole_C2_KBS5U_K11318; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a59f08de-6088-4fc4-b069-fd12ce8a0601

The open-access MAF lists 137 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 36, Silent 15, Intron 14, 3'Flank 7, 5'UTR 6, Splice Site 3, Nonsense Mutation 3, RNA 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TNNI3K | c.333+2T>C p.X111_splice | Splice Site (SNP) | VAF 41/101 reads (41%) | catalogued as rs762721434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP001781.2 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as rs201345383, COSV52787297; called by mutect2, varscan2
- CUBN | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1302204745; called by muse, mutect2, varscan2
- DOCK5 | c.4918A>G p.I1640V | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs758324521; called by muse, mutect2, varscan2
- DSN1 | c.356-1G>C p.X119_splice | Splice Site (SNP) | VAF 12/125 reads (10%) | catalogued as rs773567248; called by muse, mutect2
- EPX | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1454539064; called by muse, mutect2
- H2BC7 | c.111C>G p.S37R | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs200039236; called by muse, mutect2, varscan2
- IGHG3 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs761093846; called by muse, mutect2, varscan2
- IGLL5 | c.199T>A p.W67R | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs555906838; called by muse, varscan2
- IGLV3-1 | c.62A>C p.Y21S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs145382269; called by muse, varscan2
- IGLV3-1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs61736462; called by muse, varscan2
- IGLV3-1 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774205851; called by muse, varscan2
- IGLV4-60 | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs777668394; called by muse, mutect2, varscan2
- JMJD8 | c.402C>G p.Y134* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as rs765779943; called by muse, mutect2, varscan2
- KDM4B | c.2453T>C p.V818A | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs763025996; called by muse, mutect2, varscan2
- KIAA0930 | c.623G>A p.R208H (on ENST00000336156 / NM_001009880.2; = p.R213H on NM_015264.2) | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1569073472; called by muse, mutect2
- LMAN1 | c.1310T>C p.I437T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs199557121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LZTR1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1215353050; called by muse, mutect2, varscan2
- OR5W2 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV60618512; called by muse, mutect2, varscan2
- PRR23A | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs752206383, COSV101270348, COSV67215381; called by muse, varscan2
- RASSF9 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63432678; called by muse, mutect2, varscan2
- RYR2 | c.9317C>T p.S3106F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1007214018, COSV100772718; called by muse, mutect2, varscan2
- TACSTD2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs145032519; called by muse, mutect2, varscan2
- ZNF644 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs556547115, COSV61350182; called by muse, mutect2, varscan2
- ZNF665 | c.44G>A p.S15N (on ENST00000600412; = p.S80N on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV67215408; called by muse, mutect2, varscan2
- ASXL3 | c.2625dup p.V876Sfs*13 | Frame Shift Ins (INS) | VAF 26/74 reads (35%) | called by mutect2, varscan2
- BDKRB1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CACNG6 | c.769C>T p.H257Y (on ENST00000252729 / NM_145814.1; = p.H186Y on NM_031897.2) | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); called by muse, mutect2
- CAMSAP1 | c.1411C>A p.Q471K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CD180 | c.23T>G p.F8C | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- CFAP20DC | c.551-2A>T p.X184_splice (on ENST00000482387 / NM_001351530.2; = p.X59_splice on NM_198463.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 214/379 reads (56%) | called by muse, mutect2, varscan2
- EHD1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 120/182 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.6671C>T p.T2224I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- H2AC8 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- HECW2 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, varscan2
- ITGA11 | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 69/176 reads (39%) | called by muse, mutect2, varscan2
- IVNS1ABP | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2
- NUTM2G | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.307); called by mutect2, varscan2
- OTOGL | c.1927C>G p.H643D (on ENST00000547103; = p.H634D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); called by muse, mutect2
- PSMD14 | c.872T>A p.L291H | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PXK | c.681G>C p.M227I | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- RHOXF2 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RNF19A | c.2078T>C p.M693T | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RTTN | c.2744T>G p.V915G | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC28A2 | c.1329G>A p.W443* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- SLC5A8 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SRGAP2 | c.2401G>A p.E801K (on ENST00000624873 / NM_001170637.4; = p.E802K on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- SYNE2 | c.1670A>G p.N557S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMC7 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.034); called by muse, mutect2
- TNFRSF21 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, varscan2
- UGT1A1 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- WDHD1 | c.2317T>G p.C773G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZMYND8 | c.2789C>T p.T930I (on ENST00000311275 / NM_001363741.2; = p.T904I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); called by mutect2, varscan2
- ZNF629 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF781 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CHRM2 | c.1044G>T p.G348= | Silent (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- COL22A1 | c.2007C>T p.G669= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs374834834, COSV57351489; called by muse, mutect2, varscan2
- CSMD2 | c.9291T>C p.H3097= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs1260369121, COSV53935343; called by muse, mutect2
- FSTL5 | c.1635T>G p.V545= | Silent (SNP) | VAF 68/110 reads (62%) | called by muse, mutect2, varscan2
- GTPBP4 | c.162T>C p.T54= | Silent (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.78T>G p.S26= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs370260778; called by muse, mutect2, varscan2
- IGKV2D-29 | c.183C>T p.Y61= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs1209805018; called by muse, mutect2, varscan2
- LVRN | c.504C>T p.N168= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs752634994, COSV63497645; called by muse, mutect2, varscan2
- MAP3K21 | c.2376C>T p.S792= | Silent (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- SEMA3D | c.235A>C p.R79= | Silent (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- SHROOM2 | c.681C>T p.A227= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs530267044; called by muse, mutect2, varscan2
- SLC35E4 | c.126G>A p.R42= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs1318191468; called by muse, mutect2, varscan2
- STAG3 | c.2107C>T p.L703= | Silent (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- THBS4 | c.1785T>C p.G595= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV63471150; called by muse, mutect2, varscan2
- UNC45B | c.1032C>T p.C344= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- AAAS | c.124-112C>T | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- AAK1 | c.*10319A>T | 3'UTR (SNP) | VAF 44/85 reads (52%) | called by muse, mutect2, varscan2
- AIP | c.646-11C>A | Intron (SNP) | VAF 61/97 reads (63%) | called by muse, mutect2, varscan2
- AKAP13 | c.478+1410A>G | Intron (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- AP1G2 | c.330-62T>C | Intron (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- APOC1P1 | n.168G>T | RNA (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.302+1125C>A | Intron (SNP) | VAF 46/53 reads (87%) | called by muse, mutect2, varscan2
- ATP9A | c.*2392G>A | 3'UTR (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- BBX | c.*934A>T | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- BCLAF3 | chrX:19914001 G>A | 3'Flank (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CBX7 | c.*773G>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as rs1027378893; called by muse, mutect2, varscan2
- CCT7 | c.6+1206G>A | Intron (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- CNPY1 | c.*142T>A | 3'UTR (SNP) | VAF 66/122 reads (54%) | called by muse, varscan2
- CREB1 | c.881+4424G>A | Intron (SNP) | VAF 10/233 reads (4%) | called by muse, mutect2
- CXADR | c.*4160T>G | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- DNAJC8 | c.*842G>A | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, varscan2
- DPPA4 | c.*1402del | 3'UTR (DEL) | VAF 28/74 reads (38%) | called by mutect2, varscan2
- DTX1 | c.-393C>T | 5'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2
- DTX1 | c.-175T>C | 5'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- EGLN3 | c.357+1571T>G | Intron (SNP) | VAF 36/83 reads (43%) | called by mutect2, varscan2
- ELAVL2 | c.*546del | 3'UTR (DEL) | VAF 30/118 reads (25%) | called by mutect2, pindel, varscan2
- ENPEP | c.*2342G>T | 3'UTR (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- ENPP2 | c.-17G>A | 5'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as rs766914262; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445597 C>T | 3'Flank (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- FAM102B | c.*1152T>G | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- FBXO33 | c.*1123G>A | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- FGF9 | c.-497A>T | 5'UTR (SNP) | VAF 5/30 reads (17%) | called by mutect2, varscan2
- IL17RA | c.*3688A>C | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- INHBB | c.*495G>A | 3'UTR (SNP) | VAF 26/66 reads (39%) | catalogued as rs1397568533; called by muse, mutect2, varscan2
- IRF2BP2 | c.*1036G>C | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- JMJD1C | chr10:63466042 G>A | 5'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- KCNC1 | chr11:17781511 G>A | 3'Flank (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- LEKR1 | c.*1716A>C | 3'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- LINC00636 | n.499_502del | RNA (DEL) | VAF 60/166 reads (36%) | called by pindel, varscan2
- MBNL3 | chrX:132374076 A>G | 3'Flank (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- MED13L | c.*518C>T | 3'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- MEGF6 | c.*374C>T | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- MSX2 | c.*314T>A | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- MYLK | c.5239-2372C>G | Intron (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- NME1-NME2 | c.547-11T>C | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- OR5T1 | c.-79G>T | 5'UTR (SNP) | VAF 155/233 reads (67%) | called by muse, mutect2, varscan2
- OTUD7B | c.*745A>G | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- PHF21A | chr11:45932712 T>A | 3'Flank (SNP) | VAF 20/80 reads (25%) | catalogued as rs890191971; called by muse, mutect2, varscan2
- PLOD2 | c.1128-410G>A | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as rs964135785; called by muse, mutect2
- PTCD3 | c.*1210A>G | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- PTGER4 | c.*980G>A | 3'UTR (SNP) | VAF 26/84 reads (31%) | catalogued as rs1314219417; called by muse, mutect2, varscan2
- RBM4B | c.*21G>A | 3'UTR (SNP) | VAF 123/470 reads (26%) | called by muse, mutect2, varscan2
- RNF182 | c.*2230A>C | 3'UTR (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- RPS6KA5 | c.*1115T>G | 3'UTR (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- SCARA3 | c.*240C>T | 3'UTR (SNP) | VAF 10/27 reads (37%) | catalogued as rs532765010; called by muse, mutect2, varscan2
- SENP7 | c.2481-91T>C | Intron (SNP) | VAF 41/71 reads (58%) | called by muse, mutect2, varscan2
- SHANK1 | c.1077+48G>A | Intron (SNP) | VAF 17/40 reads (43%) | catalogued as rs528792290; called by muse, mutect2, varscan2
- SNX33 | c.*1162C>T | 3'UTR (SNP) | VAF 65/214 reads (30%) | called by muse, mutect2, varscan2
- SPRY3 | c.*680C>G | 3'UTR (SNP) | VAF 203/428 reads (47%) | called by muse, mutect2, varscan2
- SSH1 | c.*3686G>A | 3'UTR (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- STEAP1B | c.*7C>T | 3'UTR (SNP) | VAF 65/165 reads (39%) | called by muse, mutect2
- TEPP | chr16:57987585 G>C | 3'Flank (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- TFEC | c.*2732C>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- TRIM44 | c.*1250del | 3'UTR (DEL) | VAF 70/129 reads (54%) | called by mutect2, pindel, varscan2
- TRPC7 | c.-251T>G | 5'UTR (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115412096 A>T | 3'Flank (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- TTC7B | c.*110C>T | 3'UTR (SNP) | VAF 19/41 reads (46%) | catalogued as rs1483329123; called by muse, mutect2, varscan2
- UNKL | c.*1405C>T | 3'UTR (SNP) | VAF 36/79 reads (46%) | catalogued as rs970730914; called by muse, mutect2, varscan2
- VPS13C | c.9105+120A>G | Intron (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- ZNF862 | c.*1251G>A | 3'UTR (SNP) | VAF 64/132 reads (48%) | catalogued as rs1216797967, COSV56223198; called by mutect2, varscan2
- ZSCAN12 | c.*798A>G | 3'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
